Gene-level copy-number profile of tumor specimen TCGA-DQ-7592-01A from TCGA case TCGA-DQ-7592, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G2; Age at diagnosis: 57.6 years (21,041 days).
Specimen TCGA-DQ-7592-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.f56dcf26-f04f-41ff-bced-096b676093d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DQ-7592-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af5f9999-12dd-4c7a-affc-80d448719698

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 926; copy number 2: 23,338; copy number 3: 23,858; copy number 4: 6,744; copy number 5: 3,713; copy number 6: 76; copy number 7: 850; copy number 8: 58; copy number 9: 12; copy number 10: 67; copy number 14: 161; copy number 16: 1; copy number 21: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DQ-7592-01A-11D-2077-01): tumor purity 0.46, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,160 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:178,828,349–179,050,086, 2 genes, copy number 9 (within-gene range 5–9): AC092640.1, CCDC141.
- chr2:179,001,756–179,861,612, 5 genes, copy number 9 (within-gene range 2–9): RPS6P2, SESTD1, AC093911.1, RAD52P1, ZNF385B.
- chr12:66,767–34,249,958, 850 genes, copy number 7 (broad region; genes not listed).
- chr12:39,539,581–40,106,089, 7 genes, copy number 8: AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13.
- chr12:65,017,468–73,208,317, 152 genes, copy number 9–14 (broad region; genes not listed).
- chr13:71,437,966–84,902,424, 144 genes, copy number 8–21 (within-gene range 2–21) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
